Somatic mutation profile of tumor specimen C3N-01798-01 (aliquot CPT0167750007) from CPTAC case C3N-01798, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 44.3 years (16,195 days).
Specimen C3N-01798-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afaeb286-f626-44c2-99fa-c901b72446d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01798-71 (Blood Derived Normal), aliquot CPT0167810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6afa1f3a-92ae-47ca-a9f9-418c861e7a1f

The open-access MAF lists 63 somatic variants for this specimen: 41 protein-altering or splice-affecting, 14 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 14, Intron 3, 5'UTR 2, Nonsense Mutation 2, 3'UTR 2, Splice Region 1, Splice Site 1, 5'Flank 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 2940/6655 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 300/416 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABO | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 85/317 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs369099974; called by muse, mutect2, varscan2
- AIG1 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs780863970; called by muse, mutect2, varscan2
- ASTN2 | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV100528604; called by muse, mutect2, varscan2
- ATP10A | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778064047, COSV63522754; called by muse, mutect2, varscan2
- CALN1 | c.247C>T p.R83C (on ENST00000329008 / NM_001017440.3; = p.R125C on NM_031468.4) | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs758325177, COSV61118287; called by muse, mutect2, varscan2
- DENND6A | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs754343499; called by muse, mutect2, varscan2
- DNMT3A | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV53078406; called by muse, mutect2, varscan2
- FAM71E2 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1004983240; called by muse, mutect2, varscan2
- FAP | c.1968C>T p.Y656= | Splice Region (SNP) | VAF 35/105 reads (33%) | catalogued as rs201719538; called by muse, mutect2, varscan2
- FLG | c.2438G>A p.S813N | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs200198610, COSV64242907; called by muse, mutect2, varscan2
- GRM8 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 56/270 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147289844, COSV100282975; called by muse, mutect2, varscan2
- KIFC1 | c.1793C>A p.T598K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV100996041; called by muse, mutect2, varscan2
- LZTR1 | c.441_443del p.K147del | In Frame Del (DEL) | VAF 56/104 reads (54%) | catalogued as rs1278587866; called by pindel, varscan2
- MAGEB6B | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs761939709; called by muse, mutect2
- MSH4 | c.1078G>T p.V360F | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV54215004; called by muse, mutect2, varscan2
- OR8K5 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.21); catalogued as COSV57888808, COSV57889280, COSV57889510; called by muse, mutect2, varscan2
- OTUD7B | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769955651, COSV64915621; called by muse, mutect2, varscan2
- PCSK5 | c.3917G>A p.G1306E | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.4); catalogued as COSV70452311; called by muse, mutect2, varscan2
- PRUNE2 | c.8669A>G p.Q2890R | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56314376; called by muse, mutect2, varscan2
- PSTPIP1 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs750445188; called by muse, mutect2, varscan2
- PZP | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99738755; called by muse, mutect2, varscan2
- QKI | c.394A>T p.K132* | Nonsense Mutation (SNP) | VAF 42/106 reads (40%) | catalogued as rs1241329794; called by muse, mutect2, varscan2
- RYR2 | c.3121C>T p.R1041* | Nonsense Mutation (SNP) | VAF 51/125 reads (41%) | catalogued as COSV63683429; called by muse, mutect2, varscan2
- RYR2 | c.6773G>A p.R2258H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs779289104, COSV63697988; called by muse, mutect2, varscan2
- SIM1 | c.1453G>T p.G485W | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1381875931; called by muse, mutect2, varscan2
- SULF1 | c.210G>T p.M70I | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV52685908, COSV99482979; called by muse, mutect2, varscan2
- TMEM132C | c.3280C>G p.P1094A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as rs1386045604; called by muse, mutect2, varscan2
- TRPM2 | c.4442G>A p.R1481H | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.628); catalogued as rs779734671, COSV100309213; called by muse, mutect2, varscan2
- ATP10B | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CATSPER1 | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- EXOSC10 | c.1808A>C p.E603A | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.146); called by muse, mutect2
- EYA2 | c.752_753del p.G251Afs*3 | Frame Shift Del (DEL) | VAF 19/121 reads (16%) | called by mutect2, pindel, varscan2
- FANCD2 | c.1935T>A p.D645E | Missense Mutation (SNP) | VAF 45/375 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- MAGEC1 | c.1294C>G p.Q432E | Missense Mutation (SNP) | VAF 84/232 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); called by muse, varscan2
- PLPP7 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TRAV17 | chr14:21998166 del ACGCACAGT | Missense Mutation (DEL) | VAF 32/90 reads (36%) | called by mutect2, pindel
- TRIM44 | c.407A>T p.E136V | Missense Mutation (SNP) | VAF 100/288 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- U2SURP | c.2318-1G>A p.X773_splice | Splice Site (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- VPS51 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 92/249 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACAD10 | c.2544A>G p.A848= | Silent (SNP) | VAF 73/212 reads (34%) | called by muse, mutect2, varscan2
- ADARB2 | c.996G>A p.A332= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as COSV67218139; called by muse, mutect2, varscan2
- ANPEP | c.2790C>T p.F930= | Silent (SNP) | VAF 71/187 reads (38%) | catalogued as rs145116014; called by muse, mutect2, varscan2
- CACNA1B | c.5454C>T p.D1818= | Silent (SNP) | VAF 53/165 reads (32%) | catalogued as rs202244111; called by muse, mutect2, varscan2
- CD163 | c.894C>T p.Y298= | Silent (SNP) | VAF 66/174 reads (38%) | catalogued as rs778516397; called by muse, mutect2, varscan2
- COL6A6 | c.366C>T p.P122= | Silent (SNP) | VAF 58/173 reads (34%) | catalogued as rs769989127, COSV62029118, COSV62029248; called by muse, mutect2, varscan2
- EPHA6 | c.3234A>G p.A1078= | Silent (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- FRAS1 | c.3786T>C p.H1262= | Silent (SNP) | VAF 54/144 reads (38%) | called by muse, mutect2, varscan2
- GJA3 | c.513C>T p.Y171= | Silent (SNP) | VAF 122/208 reads (59%) | catalogued as rs1403675309, COSV53834825; called by muse, mutect2, varscan2
- GP9 | c.453C>T p.D151= | Silent (SNP) | VAF 82/224 reads (37%) | catalogued as rs879057925, COSV104408830; called by muse, mutect2, varscan2
- MOBP | c.279G>A p.A93= (on ENST00000420739; = p.A117= on NM_001278322.2) | Silent (SNP) | VAF 71/227 reads (31%) | catalogued as COSV60655075; called by muse, varscan2
- NME8 | c.327A>G p.K109= | Silent (SNP) | VAF 101/398 reads (25%) | catalogued as COSV99552852; called by muse, mutect2, varscan2
- PLD4 | c.204G>A p.V68= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs1224081764; called by muse, mutect2, varscan2
- PRRX1 | c.588G>A p.A196= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as rs758418083, COSV53417696; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503023 C>T | 5'Flank (SNP) | VAF 21/54 reads (39%) | catalogued as rs1423740422; called by muse, mutect2, varscan2
- AQP2 | c.-47C>T | 5'UTR (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- KIAA2013 | c.-7C>T | 5'UTR (SNP) | VAF 3/27 reads (11%) | catalogued as rs1229845804; called by muse, mutect2
- KLHL29 | c.940+177G>A | Intron (SNP) | VAF 29/76 reads (38%) | catalogued as rs1359493613; called by muse, mutect2
- SERPINA4 | c.-18+114C>T | Intron (SNP) | VAF 72/226 reads (32%) | catalogued as rs559530503; called by muse, mutect2, varscan2
- SYTL2 | c.1459+908A>C | Intron (SNP) | VAF 28/151 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.*1G>C | 3'UTR (SNP) | VAF 26/55 reads (47%) | catalogued as rs1192756689; called by muse, mutect2, varscan2
- ZNF536 | c.*15G>A | 3'UTR (SNP) | VAF 23/46 reads (50%) | catalogued as rs201214050; called by muse, mutect2, varscan2
